Somatic mutation profile of tumor specimen TCGA-DK-A3IK-01A (aliquot TCGA-DK-A3IK-01A-32D-A21A-08) from TCGA case TCGA-DK-A3IK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 87.8 years (32,076 days).
Specimen TCGA-DK-A3IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 867838ab-4477-4978-b950-39c95e6bc60f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IK-10A (Blood Derived Normal), aliquot TCGA-DK-A3IK-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8799d717-202d-429d-b44a-7fd1c877816b

The open-access MAF lists 220 somatic variants for this specimen: 171 protein-altering or splice-affecting, 45 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 45, Nonsense Mutation 11, Splice Site 2, 5'Flank 1, Frame Shift Del 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.2153G>A p.W718* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs398124268, CM116365; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 66/119 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.983); catalogued as COSV59247560, COSV59247830; called by muse, mutect2, varscan2
- ADAMTS15 | c.2018G>C p.G673A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV54504588; called by muse, mutect2
- ADCY8 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.33); catalogued as rs557261841, COSV53899564; called by muse, mutect2, varscan2
- AHNAK2 | c.7799C>T p.A2600V | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs376661887; called by muse, mutect2, varscan2
- ALDH1A1 | c.1124G>C p.W375S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as COSV52790569; called by muse, mutect2, varscan2
- ANAPC7 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV71443793; called by muse, mutect2, varscan2
- ANKFN1 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as COSV100592955, COSV59445270; called by muse, mutect2, varscan2
- AP2A1 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV62818064; called by muse, mutect2, varscan2
- ARHGAP32 | c.1261G>A p.E421K (on ENST00000310343 / NM_001378025.1; = p.E72K on NM_014715.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV59846120; called by muse, mutect2, varscan2
- ARID1A | c.6619C>T p.Q2207* | Nonsense Mutation (SNP) | VAF 65/137 reads (47%) | catalogued as COSV61374784; called by muse, mutect2, varscan2
- ARL13B | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV57397582; called by muse, mutect2, varscan2
- ARL16 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as COSV61266634, COSV61267465; called by muse, mutect2, varscan2
- ARMC12 | c.946C>G p.L316V (on ENST00000373866 / NM_001286574.2; = p.L343V on NM_145028.5) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55359842; called by muse, mutect2, varscan2
- ARMCX1 | c.113G>C p.W38S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV65705039; called by muse, mutect2, varscan2
- ASGR1 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52648696; called by muse, mutect2, varscan2
- ATG2B | c.2937C>G p.F979L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs113424169, COSV63422680; called by muse, varscan2
- ATP2A1 | c.2865G>A p.M955I | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV62869061; called by muse, mutect2
- BHLHE41 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54378519, COSV54379410; called by muse, mutect2, varscan2
- BTBD7 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.971); catalogued as rs1279472344, COSV100598015, COSV58284980; called by muse, mutect2, varscan2
- C2orf16 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV68645860; called by muse, mutect2, varscan2
- CC2D1B | c.2019G>T p.Q673H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV52559846; called by muse, mutect2, varscan2
- CCDC62 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV53432396; called by muse, mutect2, varscan2
- CDC14B | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55786826; called by muse, mutect2, varscan2
- CDH15 | c.2047G>C p.G683R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV57023478; called by muse, mutect2, varscan2
- CHD5 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as rs866020323, COSV52412320; called by muse, mutect2, varscan2
- CNN1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs560009499, COSV52947596; called by muse, mutect2, varscan2
- COMP | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.948); catalogued as COSV55874350; called by muse, mutect2, varscan2
- CTSE | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs371242472; called by muse, mutect2, varscan2
- CUBN | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1324700124, COSV64713319; called by muse, mutect2, varscan2
- CUBN | c.3089T>A p.L1030H | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV64713326; called by muse, mutect2, varscan2
- CYP11B2 | c.1469G>C p.R490T | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59995518; called by muse, mutect2
- DCAF11 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV58108814; called by muse, mutect2, varscan2
- DDN | c.1215G>C p.W405C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV60292180, COSV60292313; called by muse, mutect2, varscan2
- DGCR8 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 76/622 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV61226298; called by muse, mutect2, varscan2
- DHX34 | c.1546C>G p.P516A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs760692334, COSV60894374, COSV60895089; called by muse, mutect2, varscan2
- DIDO1 | c.3776G>T p.G1259V | Missense Mutation (SNP) | VAF 73/376 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV56619154; called by muse, mutect2, varscan2
- DLGAP4 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1555902840, COSV59416666; called by muse, mutect2, varscan2
- DNAJC28 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58721489; called by muse, mutect2, varscan2
- DROSHA | c.2156T>C p.I719T | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV60774744; called by muse, mutect2, varscan2
- E2F1 | c.1087G>C p.G363R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV55775618; called by muse, mutect2
- EIF5B | c.1811G>C p.R604T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs777933430, COSV56812372; called by muse, mutect2, varscan2
- ENPP1 | c.2582G>A p.R861K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV62931677; called by muse, mutect2, varscan2
- FAM50B | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs763572373, COSV66654691; called by muse, mutect2, varscan2
- FARSA | c.1287G>C p.W429C | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53366295; called by muse, mutect2, varscan2
- FBXO27 | c.495G>C p.Q165H | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53072198; called by muse, mutect2, varscan2
- FCRL5 | c.2642C>G p.P881R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV62513368; called by muse, mutect2, varscan2
- FNDC3A | c.1637A>C p.E546A (on ENST00000492622 / NM_001079673.2; = p.E490A on NM_014923.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV68132770; called by muse, mutect2, varscan2
- FNIP1 | c.3128C>G p.P1043R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57195365; called by muse, mutect2, varscan2
- FOXF2 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52525501; called by muse, mutect2, varscan2
- FST | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV56815419; called by muse, mutect2, varscan2
- G2E3 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as COSV52839741; called by muse, mutect2, varscan2
- GAS6 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV59849263; called by muse, mutect2, varscan2
- GBF1 | c.3201G>C p.E1067D (on ENST00000369983 / NM_001377137.1; = p.E1066D on NM_004193.3) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); catalogued as COSV64144223; called by muse, mutect2, varscan2
- GCN1 | c.2631C>G p.I877M | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as COSV56106455, COSV56112925; called by muse, mutect2, varscan2
- GLE1 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as COSV59407363; called by muse, mutect2, varscan2
- GNPTAB | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs1566073911, COSV68449679; called by muse, mutect2, varscan2
- GSTA1 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58015073; called by muse, mutect2, varscan2
- GSTA5 | c.180T>G p.I60M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.487); catalogued as COSV52861945; called by muse, mutect2, varscan2
- H2BC21 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 170/346 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2, varscan2
- HDDC3 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV100376622; called by muse, mutect2, varscan2
- HEPH | c.2788G>A p.E930K (on ENST00000343002; = p.E663K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476939767; called by muse, mutect2, varscan2
- HIPK4 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.596); catalogued as COSV52520411; called by muse, mutect2, varscan2
- HJURP | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV68577771, COSV68579663; called by muse, mutect2, varscan2
- HMGA2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as COSV67803205; called by muse, mutect2, varscan2
- HPSE2 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs751015169, COSV65186620; called by muse, mutect2, varscan2
- IGSF9B | c.3610C>G p.L1204V | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as COSV58066306; called by muse, mutect2, varscan2
- INTS3 | c.432+2T>C p.X144_splice | Splice Site (SNP) | VAF 24/43 reads (56%) | catalogued as COSV59676706; called by muse, mutect2
- IQSEC2 | c.3003T>A p.N1001K (on ENST00000642864 / NM_001111125.3; = p.N796K on NM_015075.2) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64724768; called by muse, mutect2, varscan2
- ISG20 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs770868397, COSV60143663; called by muse, mutect2, varscan2
- ITGA7 | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV57694065; called by muse, mutect2
- JHY | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1364181517, COSV56218864; called by muse, mutect2, varscan2
- KIAA1109 | c.11799G>C p.Q3933H | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52668858; called by muse, mutect2, varscan2
- KIR3DL1 | c.1178C>G p.P393R | Missense Mutation (SNP) | VAF 95/599 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV58489785; called by muse, mutect2, varscan2
- KIRREL3 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69384088; called by muse, mutect2, varscan2
- KLF11 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59940379; called by muse, mutect2, varscan2
- KMT2B | c.2148G>C p.K716N | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52890124; called by muse, mutect2, varscan2
- KRR1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1309560214, COSV57518966; called by muse, mutect2
- LAMA3 | c.8950C>T p.H2984Y (on ENST00000313654 / NM_198129.4; = p.H1375Y on NM_000227.6) | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs769727886, COSV52533217; called by muse, mutect2, varscan2
- LILRA1 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 43/289 reads (15%) | catalogued as COSV52185048; called by muse, mutect2, varscan2
- LRFN5 | c.1988T>C p.V663A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1306939149, COSV53251688; called by muse, varscan2
- LRRC7 | c.4068G>C p.Q1356H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV50435690, COSV50439894; called by muse, mutect2, varscan2
- MAVS | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs761713524, COSV63926736; called by muse, mutect2, varscan2
- MERTK | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54923873, COSV54927563, COSV54934013; called by muse, mutect2, varscan2
- MLLT1 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53129959, COSV53130123; called by muse, mutect2, varscan2
- MRTFB | c.2458G>A p.A820T (on ENST00000571589 / NM_001365412.2; = p.A770T on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1031195761, COSV57957262; called by muse, mutect2, varscan2
- MVP | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 169/281 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV62421860; called by muse, mutect2, varscan2
- MYH3 | c.4282G>A p.D1428N | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56863506; called by muse, mutect2, varscan2
- MYO6 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as rs768543476, COSV64118590; called by muse, mutect2, varscan2
- NCAPD2 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as COSV59698807; called by muse, mutect2, varscan2
- NES | c.3769G>C p.G1257R | Missense Mutation (SNP) | VAF 35/353 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV63960748, COSV63963087; called by muse, mutect2
- NFYA | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV58198313; called by muse, mutect2, varscan2
- NIBAN1 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as COSV62284275; called by muse, mutect2, varscan2
- OSBPL5 | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55141042; called by muse, mutect2, varscan2
- PADI2 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64953651; called by muse, mutect2
- PADI4 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs750630189, COSV100966954, COSV64923768; called by muse, mutect2, varscan2
- PBOV1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV52454929; called by muse, mutect2, varscan2
- PCDH1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as rs749448423, COSV54613132; called by muse, mutect2, varscan2
- PCED1B | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs759220333, COSV71395095; called by muse, mutect2, varscan2
- PCNT | c.7366G>A p.V2456I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.275); catalogued as COSV64027099, COSV64032074; called by muse, mutect2, varscan2
- PCSK4 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV52013042; called by muse, mutect2, varscan2
- PCSK5 | c.5273G>A p.G1758E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV70447485, COSV70448908; called by muse, mutect2, varscan2
- PHACTR3 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs759238957; called by muse, mutect2, varscan2
- PITPNM1 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62708007; called by muse, mutect2, varscan2
- PNPLA7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52997441; called by muse, mutect2, varscan2
- POLE | c.5023C>T p.R1675C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027297469, COSV57678225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIB | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV55519909; called by muse, mutect2, varscan2
- PSPH | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV51910304; called by muse, mutect2, varscan2
- PTCD1 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV52862642; called by muse, mutect2, varscan2
- PTPRD | c.2117C>G p.T706S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV61938496; called by muse, mutect2, varscan2
- RFTN1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as COSV61918186; called by muse, mutect2, varscan2
- RGS22 | c.700T>G p.S234A | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV62660362; called by muse, mutect2, varscan2
- RNF126 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52778827; called by muse, mutect2, varscan2
- RTKN | c.149G>T p.R50L (on ENST00000272430 / NM_001015055.2; = p.R37L on NM_033046.2) | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51962462; called by muse, mutect2, varscan2
- SETD1A | c.4739G>T p.W1580L | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52680287; called by muse, mutect2, varscan2
- SETD4 | c.1269G>C p.K423N | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV59771881; called by muse, mutect2, varscan2
- SH3GL1 | c.564G>C p.E188D | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as COSV53656306, COSV53656725; called by muse, mutect2, varscan2
- SLC4A4 | c.2512C>T p.L838F (on ENST00000264485 / NM_001098484.3; = p.L794F on NM_003759.4) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52616525; called by muse, mutect2
- SPATA7 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50416531; called by muse, mutect2, varscan2
- SPSB2 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51290110; called by muse, varscan2
- SPTBN1 | c.5995A>T p.R1999W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61687577; called by muse, mutect2, varscan2
- STOX1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs547404717, COSV53814237; called by muse, mutect2, varscan2
- SULF1 | c.2041A>T p.S681C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV52678930; called by muse, mutect2, varscan2
- TAOK3 | c.2527G>C p.E843Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV66825427; called by muse, mutect2, varscan2
- TAOK3 | c.1967C>A p.T656N | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66825430; called by muse, mutect2, varscan2
- TBCD | c.2711G>T p.C904F | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62799750; called by muse, mutect2
- TINAG | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV52508375; called by muse, mutect2, varscan2
- TIPRL | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 159/200 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV63208612; called by muse, mutect2, varscan2
- TMEM225 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV66693071; called by muse, mutect2, varscan2
- TMEM94 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV58599034; called by muse, mutect2, varscan2
- TNNT1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV52571458; called by muse, mutect2, varscan2
- TOM1 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65897823; called by muse, mutect2, varscan2
- TTC39A | c.1237G>A p.E413K (on ENST00000447632 / NM_001297665.1; = p.E378K on NM_001080494.3) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.71); PolyPhen benign (0.157); catalogued as rs1335918634, COSV52957549; called by muse, mutect2, varscan2
- TTYH3 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51859582; called by muse, mutect2, varscan2
- UBAP2 | c.1837A>G p.M613V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs1262951881, COSV62546261; called by muse, mutect2, varscan2
- UBASH3A | c.1289A>T p.D430V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52311811; called by muse, mutect2, varscan2
- UBE3C | c.1602G>C p.M534I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV61952561; called by muse, mutect2, varscan2
- UGT1A6 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 96/412 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV59386572; called by muse, mutect2, varscan2
- UGT1A9 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.404); catalogued as rs762262088, COSV60836142; called by muse, mutect2, varscan2
- USP48 | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as COSV57608975; called by mutect2, varscan2
- UTP6 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV55572635; called by muse, mutect2, varscan2
- VIT | c.1473G>C p.L491F (on ENST00000389975 / NM_001177969.1; = p.L506F on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1205143092, COSV64896167; called by muse, mutect2, varscan2
- VPS8 | c.3808G>C p.E1270Q (on ENST00000625842 / NM_001349294.1; = p.E1268Q on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as COSV54983481; called by muse, mutect2
- WDR90 | c.4807G>T p.V1603F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV53468472, COSV53468939; called by muse, mutect2, varscan2
- YAE1 | c.519G>C p.K173N | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV56232853; called by muse, mutect2, varscan2
- ZCCHC3 | c.585G>C p.M195I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV66643085; called by muse, mutect2
- ZFPM2 | c.1094G>A p.C365Y | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65873118; called by muse, mutect2, varscan2
- ZHX2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58711988; called by muse, mutect2
- ZNF227 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as rs754012306, COSV57311971; called by muse, mutect2, varscan2
- ZNF383 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV61938994; called by muse, mutect2, varscan2
- ZNF385D | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55751844, COSV99874535; called by muse, mutect2, varscan2
- ZNF436 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58358378; called by muse, mutect2, varscan2
- ZNF483 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV58515643; called by muse, mutect2, varscan2
- ZNF626 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52480809; called by muse, mutect2, varscan2
- ZNF750 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs200817916, COSV53959747; called by muse, mutect2, varscan2
- ZNF76 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs770847048, COSV57353781; called by muse, mutect2, varscan2
- ZSCAN25 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.193); catalogued as COSV53552699; called by muse, mutect2, varscan2
- ZSCAN25 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs755130158, COSV53552431; called by muse, varscan2
- AFDN | c.485C>G p.S162* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- DUSP6 | c.839-3_854del p.X280_splice | Splice Site (DEL) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- ERBIN | c.212T>C p.L71S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHG1 | c.479G>C p.W160S | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JADE1 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 49/224 reads (22%) | called by muse, mutect2, varscan2
- OR2B3 | c.826del p.L276Sfs*10 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- OR5B17 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); called by muse, mutect2
- PNPLA7 | c.3871G>T p.E1291* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- QPRT | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2
- TIMM23 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF112 | c.2089G>C p.E697Q (on ENST00000337401 / NM_001083335.2; = p.E691Q on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.147); called by muse, mutect2
- ZSCAN25 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | called by muse, varscan2
- ADARB1 | c.2040C>T p.H680= (on ENST00000360697 / NM_001346687.2; = p.H640= on NM_001112.4) | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1416977292, COSV62349378; called by muse, mutect2
- ALDH1L2 | c.1743G>A p.K581= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV51554900; called by muse, mutect2, varscan2
- ASAP3 | c.1407C>G p.R469= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV60874156; called by muse, mutect2, varscan2
- CDH17 | c.516C>T p.P172= | Silent (SNP) | VAF 41/447 reads (9%) | catalogued as rs1462698952, COSV50327287; called by muse, mutect2
- CPT1A | c.2262G>C p.L754= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV55754984; called by muse, mutect2, varscan2
- CXCL16 | c.186G>C p.L62= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV52641195; called by muse, mutect2, varscan2
- CYP2A7 | c.481C>A p.R161= | Silent (SNP) | VAF 35/249 reads (14%) | catalogued as COSV52500160; called by muse, mutect2, varscan2
- CYRIA | c.81T>C p.P27= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- DDX20 | c.2292G>A p.L764= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as rs368560972, COSV63779487; called by muse, mutect2
- EMID1 | c.780C>A p.P260= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV61829090; called by muse, mutect2
- FAT2 | c.11934C>T p.F3978= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as COSV55817620; called by muse, mutect2, varscan2
- FBXL14 | c.294C>T p.S98= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs1178122274, COSV59336021; called by muse, mutect2, varscan2
- FBXO46 | c.18C>T p.L6= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV58348336; called by muse, mutect2
- GBF1 | c.5508C>T p.I1836= (on ENST00000369983 / NM_001377137.1; = p.I1835= on NM_004193.3) | Silent (SNP) | VAF 51/240 reads (21%) | catalogued as rs1419763659, COSV64144231; called by muse, mutect2, varscan2
- GRIA2 | c.2079C>T p.T693= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
- HERC5 | c.867G>T p.V289= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV52039024; called by muse, mutect2, varscan2
- HK3 | c.2592G>C p.V864= | Silent (SNP) | VAF 40/332 reads (12%) | catalogued as rs775211830, COSV52838863; called by muse, mutect2, varscan2
- IGHA1 | c.429G>C p.A143= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs372204054; called by muse, mutect2, varscan2
- IRGC | c.1023G>A p.E341= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV54983732; called by muse, mutect2, varscan2
- KDM1B | c.1932G>A p.L644= (on ENST00000449850; = p.L411= on NM_153042.4) | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as COSV52809967; called by muse, mutect2
- KRTAP10-7 | c.696C>G p.V232= | Silent (SNP) | VAF 64/487 reads (13%) | catalogued as rs782205929, COSV59110003; called by muse, mutect2, varscan2
- KRTAP19-1 | c.237G>A p.S79= | Silent (SNP) | VAF 37/323 reads (11%) | catalogued as rs201791168, COSV66861149; called by muse, mutect2, varscan2
- MBD3 | c.384G>A p.Q128= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as rs1210619890, COSV104381226, COSV50083024; called by muse, mutect2, varscan2
- MSC | c.510C>T p.N170= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs1478797721, COSV57696514; called by muse, mutect2, varscan2
- NUTM1 | c.1014C>G p.A338= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV59216529; called by muse, mutect2, varscan2
- PABPC1 | c.1284T>C p.I428= | Silent (SNP) | VAF 63/422 reads (15%) | catalogued as COSV59400646; called by muse, mutect2, varscan2
- PLCH1 | c.1776G>A p.R592= (on ENST00000340059 / NM_001130960.2; = p.R604= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV58188626; called by muse, mutect2, varscan2
- RNF150 | c.669C>A p.S223= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV60789477; called by muse, mutect2, varscan2
- ROBO4 | c.1416C>G p.A472= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60623021; called by muse, mutect2, varscan2
- RPN2 | c.1878C>G p.V626= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs1446749130, COSV52905006; called by muse, mutect2, varscan2
- SCIN | c.1284C>G p.L428= (on ENST00000297029 / NM_001112706.3; = p.L181= on NM_033128.3) | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as rs1447520383, COSV51691566; called by muse, mutect2, varscan2
- SEMA3D | c.918C>G p.A306= | Silent (SNP) | VAF 91/193 reads (47%) | catalogued as COSV52391390; called by muse, mutect2, varscan2
- SH3YL1 | c.351C>G p.G117= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV62156057; called by muse, mutect2, varscan2
- SLC4A4 | c.2421C>T p.N807= (on ENST00000264485 / NM_001098484.3; = p.N763= on NM_003759.4) | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- SP110 | c.114A>G p.L38= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs943542557, COSV51249053; called by muse, mutect2, varscan2
- SPTAN1 | c.5988G>A p.E1996= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV63986475; called by muse, mutect2, varscan2
- STK40 | c.1188G>T p.R396= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV63735184; called by muse, mutect2
- SYT6 | c.868C>T p.L290= (on ENST00000610222 / NM_001366225.1; = p.L205= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV65773382; called by muse, mutect2, varscan2
- TBC1D13 | c.222G>C p.L74= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV56353947; called by muse, mutect2, varscan2
- TBX5 | c.493C>T p.L165= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1388916093, COSV59860105; called by muse, mutect2, varscan2
- TCP1 | c.24C>T p.F8= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV58458277; called by muse, mutect2, varscan2
- TNK2 | c.570C>T p.I190= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs1560517562, COSV57368106; called by muse, mutect2, varscan2
- VSTM2L | c.369C>T p.I123= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV65095780; called by muse, mutect2, varscan2
- XIRP1 | c.5248C>T p.L1750= | Silent (SNP) | VAF 40/238 reads (17%) | catalogued as COSV61137936; called by muse, mutect2, varscan2
- ZNF84 | c.849G>C p.R283= | Silent (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- EBAG9 | c.522-1040C>G | Intron (SNP) | VAF 443/707 reads (63%) | catalogued as COSV61752925; called by muse, mutect2, varscan2
- NDUFB8 | c.-1G>C | 5'UTR (SNP) | VAF 12/49 reads (24%) | catalogued as rs760545213, COSV100144188; called by muse, mutect2, varscan2
- SSPOP | n.5952G>A | RNA (SNP) | VAF 6/16 reads (38%) | catalogued as rs542037603, COSV50486380; called by muse, varscan2
- ZBTB37 | chr1:173864890 G>A | 5'Flank (SNP) | VAF 17/266 reads (6%) | called by muse, mutect2
